MMRF case MMRF_1033 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a3b3a7dd-8559-4b01-8112-d15ec35c5550

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.9 years (23,692 days); ISS stage: I; Days to last known disease status: 1,786 days (4.9 years); Days to last follow up: 1,786 days (4.9 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 123 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -29 (ECOG 0): M Protein 2.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 129 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.351 mg/dL; Immunoglobulin G 44.1 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 1.51 µg/mL; Hemoglobin 8.8 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 3.99 ×10⁹/L; Platelets 307 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.53 mmol/L; Albumin 40 g/L; Total Protein 9.3 g/dL; Glucose 5.89 mmol/L; C-Reactive Protein 0.13 mg/dL.
- Day 89 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.436 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 7.01 ×10⁹/L; Absolute Neutrophil 4.11 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 5.06 mmol/L.
- Day 152 (ECOG 0): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.734 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 1.37 µg/mL; Hemoglobin 9.24 mmol/L; Leukocytes 4.58 ×10⁹/L; Absolute Neutrophil 2.64 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 7.4 g/dL; Glucose 8.25 mmol/L.
- Day 218: M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.337 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 1.5 µg/mL; Hemoglobin 8.87 mmol/L; Leukocytes 6.31 ×10⁹/L; Absolute Neutrophil 3.53 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 5.61 mmol/L.
- Day 328 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.325 mg/dL; Immunoglobulin G 15.2 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 1.77 µg/mL; Hemoglobin 8.56 mmol/L; Leukocytes 6.39 ×10⁹/L; Absolute Neutrophil 3.54 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 6.05 mmol/L.
- Day 425 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 17.2 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 1.3 µg/mL; Hemoglobin 9.11 mmol/L; Leukocytes 7.08 ×10⁹/L; Absolute Neutrophil 4.66 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 5.34 mmol/L.
- Day 515 (ECOG 0): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.312 mg/dL; Immunoglobulin G 18.1 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 1.25 µg/mL; Hemoglobin 9.3 mmol/L; Leukocytes 7.27 ×10⁹/L; Absolute Neutrophil 4.57 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.75 mmol/L; Albumin 46 g/L; Total Protein 7.8 g/dL; Glucose 4.62 mmol/L.
- Day 593 (ECOG 1): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.327 mg/dL; Immunoglobulin G 17.6 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 1.44 µg/mL; Hemoglobin 9.11 mmol/L; Leukocytes 6.34 ×10⁹/L; Absolute Neutrophil 3.69 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 5.23 mmol/L.
- Day 679 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 27.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 20.2 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 1.42 µg/mL; Hemoglobin 8.8 mmol/L; Leukocytes 8.63 ×10⁹/L; Absolute Neutrophil 5.57 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.53 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 6.16 mmol/L.
- Day 799 (ECOG 0): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 35.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 22.4 g/L; Immunoglobulin A 1.1 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 1.43 µg/mL; Hemoglobin 9.55 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.58 mmol/L; Albumin 45 g/L; Total Protein 8.3 g/dL; Glucose 6.99 mmol/L.
- Day 874 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 35.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.32 mg/dL; Immunoglobulin G 17.6 g/L; Immunoglobulin A 0.94 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.39 µg/mL; Hemoglobin 8.8 mmol/L; Leukocytes 6.92 ×10⁹/L; Absolute Neutrophil 4.54 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.5 mmol/L; Albumin 45 g/L; Total Protein 7.7 g/dL; Glucose 5.78 mmol/L.
- Day 939 (ECOG 0): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.47 mg/dL; Immunoglobulin G 19.6 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.38 µg/mL; Hemoglobin 8.87 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.58 mmol/L; Glucose 6.22 mmol/L.
- Day 1,044 (ECOG 0): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 44.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.33 mg/dL; Immunoglobulin G 21.5 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 1.5 µg/mL; Hemoglobin 8.99 mmol/L; Leukocytes 7.92 ×10⁹/L; Absolute Neutrophil 4.97 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.53 mmol/L; Albumin 45 g/L; Total Protein 8.1 g/dL; Glucose 5.94 mmol/L.
- Day 1,113: M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 47.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.39 mg/dL; Immunoglobulin G 19.4 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.55 µg/mL; Hemoglobin 8.56 mmol/L; Leukocytes 12.1 ×10⁹/L; Absolute Neutrophil 9.07 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 5.67 mmol/L.
- Day 1,212 (ECOG 0): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 50.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 21.4 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 1.45 µg/mL; Hemoglobin 8.99 mmol/L; Leukocytes 7.73 ×10⁹/L; Absolute Neutrophil 5.43 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 7.7 g/dL; Glucose 9.08 mmol/L.
- Day 1,337 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 56.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.39 mg/dL; Immunoglobulin G 24.4 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 1.81 µg/mL; Hemoglobin 9.24 mmol/L; Leukocytes 7.58 ×10⁹/L; Absolute Neutrophil 4.57 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 46 g/L; Total Protein 8.3 g/dL; Glucose 6.55 mmol/L.
- Day 1,426 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 52.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 23 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 1.98 µg/mL; Hemoglobin 9.05 mmol/L; Leukocytes 6.76 ×10⁹/L; Absolute Neutrophil 4.17 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 8.1 g/dL; Glucose 5.89 mmol/L.
- Day 1,525 (ECOG 0): M Protein 2.2 g/dL; Immunoglobulin G 24.6 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 1.81 µg/mL; Hemoglobin 9.36 mmol/L; Leukocytes 6.18 ×10⁹/L; Absolute Neutrophil 3.82 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.58 mmol/L; Albumin 42 g/L; Total Protein 8.1 g/dL; Glucose 6.33 mmol/L.
- Day 1,610 (ECOG 0): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 50.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 23.5 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.48 g/L; Beta 2 Microglobulin 1.97 µg/mL; Hemoglobin 8.93 mmol/L; Leukocytes 6.31 ×10⁹/L; Absolute Neutrophil 3.59 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.7 mmol/L; Albumin 44 g/L; Total Protein 8.8 g/dL; Glucose 5.72 mmol/L.
- Day 1,700: M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 53.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.32 mg/dL; Immunoglobulin G 24.4 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 2.08 µg/mL; Hemoglobin 9.11 mmol/L; Leukocytes 7.64 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 8.2 g/dL; Glucose 5.39 mmol/L.
- Day 1,786: M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 53.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 26.4 g/L; Immunoglobulin A 0.94 g/L; Immunoglobulin M 0.48 g/L; Beta 2 Microglobulin 1.55 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 11.2 ×10⁹/L; Absolute Neutrophil 8.6 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.55 mmol/L; Albumin 46 g/L; Total Protein 8.7 g/dL; Glucose 6.55 mmol/L.

Other clinical attributes
- Day -29: Weight: 72 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1033_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -29 days.
- Sample MMRF_1033_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -29 days.
